Somatic mutation profile of tumor specimen MMRF_2273_1_BM_CD138pos (aliquot MMRF_2273_1_BM_CD138pos_T1_KHS5U_L11031) from MMRF case MMRF_2273, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.1 years (25,239 days).
Specimen MMRF_2273_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52e66666-b4cd-49c5-920e-eb2ae23ab045.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2273_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2273_1_PB_WBC_C2_KHS5U_L11032; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f5e5382-dc58-42e4-9e98-b3b47645214b

The open-access MAF lists 192 somatic variants for this specimen: 86 protein-altering or splice-affecting, 18 silent, 88 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, 3'UTR 45, Silent 18, Intron 17, 5'UTR 12, 3'Flank 6, Nonsense Mutation 5, Frame Shift Del 4, 5'Flank 4, RNA 4, Splice Site 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CWC27 | c.1002del p.V335* | Frame Shift Del (DEL) | VAF 56/92 reads (61%) | catalogued as rs752159903; ClinVar: pathogenic; called by mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 125/252 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TULP1 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748972748, CM095222; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALPK3 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.832); catalogued as rs140420563; called by muse, mutect2, varscan2
- AP3B2 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866031332, COSV99916989; called by muse, mutect2
- CCDC185 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs754754030, COSV64820292, COSV99081317; called by muse, mutect2, varscan2
- CD164 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as rs1158527629; called by muse, mutect2, varscan2
- CDH9 | c.998A>T p.Q333L | Missense Mutation (SNP) | VAF 134/245 reads (55%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV50258828; called by muse, mutect2, varscan2
- CFAP46 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs768005068; called by muse, mutect2, varscan2
- DNHD1 | c.13165C>A p.P4389T | Missense Mutation (SNP) | VAF 61/109 reads (56%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.548); catalogued as rs996050527; called by muse, mutect2, varscan2
- EGR1 | c.103C>G p.L35V | Missense Mutation (SNP) | VAF 65/265 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs558452520, COSV53520131; called by muse, varscan2
- EXT2 | c.1201C>T p.Q401* (on ENST00000343631; = p.Q434* on NM_000401.3) | Nonsense Mutation (SNP) | VAF 38/145 reads (26%) | catalogued as CD065715, CM970454, COSV59156361; called by muse, mutect2, varscan2
- FAM71E2 | c.2362T>C p.W788R | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs758383859; called by muse, mutect2, varscan2
- GASK1A | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 75/131 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs761834645, COSV56182881; called by muse, mutect2, varscan2
- HMCN2 | c.12616G>A p.V4206I | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.118); catalogued as rs573213826; called by muse, mutect2, varscan2
- IGHV2-70 | c.48G>A p.W16* | Nonsense Mutation (SNP) | VAF 24/86 reads (28%) | catalogued as rs375927713; called by muse, varscan2
- IGHV2-70D | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194006557; called by muse, varscan2
- IGKV4-1 | c.186C>A p.Y62* | Nonsense Mutation (SNP) | VAF 34/67 reads (51%) | catalogued as rs374903238; called by muse, mutect2, varscan2
- IGLV3-1 | c.49T>A p.S17T | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as rs572483152; called by muse, varscan2
- IGLV3-1 | c.130G>C p.D44H | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs371113616; called by muse, varscan2
- IGLV3-1 | c.277A>C p.I93L | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs548457166; called by muse, varscan2
- INHBE | c.86G>A p.C29Y | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483826114; called by muse, mutect2, varscan2
- ITGB4 | c.5228C>T p.P1743L | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.415); catalogued as rs368445689; called by muse, mutect2, varscan2
- KCNK6 | c.395del p.P132Rfs*7 | Frame Shift Del (DEL) | VAF 69/349 reads (20%) | catalogued as COSV99649395; called by mutect2, pindel, varscan2
- KLHL6 | c.281G>C p.S94T | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58066112, COSV58066766, COSV58067520; called by muse, mutect2, varscan2
- LURAP1L | c.135dup p.S46Efs*13 | Frame Shift Ins (INS) | VAF 27/122 reads (22%) | catalogued as rs776154291; called by mutect2, pindel, varscan2
- MYO1F | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs778366731; called by muse, mutect2, varscan2
- OR2AG1 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as rs183362075; called by muse, mutect2, varscan2
- PCDHB16 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 85/157 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1318451722, COSV53367591; called by muse, mutect2, varscan2
- PCSK1N | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1557033513; called by muse, mutect2
- RHOBTB1 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763301456, COSV61958168; called by muse, mutect2, varscan2
- RUSC2 | c.2699G>T p.R900M | Missense Mutation (SNP) | VAF 122/250 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63429163; called by muse, mutect2, varscan2
- SOAT1 | c.329+1G>A p.X110_splice | Splice Site (SNP) | VAF 18/50 reads (36%) | catalogued as COSV62654570; called by muse, mutect2, varscan2
- SOS1 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.793); catalogued as COSV67673755; called by muse, mutect2, varscan2
- SPATA3 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 20/329 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs955456004; called by muse, mutect2
- SPHKAP | c.2461C>A p.P821T | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV60870040; called by muse, mutect2, varscan2
- USP10 | c.1475A>T p.D492V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54753827; called by muse, mutect2, varscan2
- VWA7 | c.1111A>G p.S371G | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as rs753090338; called by muse, varscan2
- ZNF627 | c.1023del p.A343Pfs*192 | Frame Shift Del (DEL) | VAF 63/159 reads (40%) | catalogued as COSV100741439; called by mutect2, pindel, varscan2
- ADAM22 | c.2160T>A p.D720E | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRB3 | c.735G>T p.E245D | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ATRX | c.3053A>G p.K1018R | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CBX8 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCDC7 | c.3624A>C p.L1208F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- CCNA2 | c.191A>C p.Q64P | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP54 | c.4427A>T p.E1476V | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CPSF6 | c.94T>G p.L32V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- CPXM2 | c.1705G>A p.V569M | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- CSNK2A1 | c.176_177del p.I59Nfs*3 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- CTTNBP2 | c.1664C>A p.T555N | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- EFCAB12 | c.838+4C>T | Splice Region (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- ERO1B | c.1214A>G p.Q405R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2
- FBXW2 | c.701A>C p.Y234S | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FUBP1 | c.1926+2T>A p.X642_splice | Splice Site (SNP) | VAF 6/20 reads (30%) | called by muse, varscan2
- FUBP1 | c.1862A>G p.Q621R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, varscan2
- GGT5 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- GRM7 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- H3C7 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 80/283 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- HS6ST2 | c.1390G>T p.A464S | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGHV2-70D | c.136T>C p.F46L | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.189); called by muse, varscan2
- IL32 | c.255G>A p.V85= (on ENST00000396890 / NM_001308078.4; = p.V39= on NM_004221.7 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 28/89 reads (31%) | called by muse, mutect2, varscan2
- ITGAL | c.1834T>A p.S612T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ITGAX | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNK1 | c.335G>A p.S112N | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIR3DL1 | c.1181A>T p.E394V | Missense Mutation (SNP) | VAF 78/394 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LIN7B | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRIG1 | c.893T>A p.I298N | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- MCC | c.62_63insTGG p.G21dup | In Frame Ins (INS) | VAF 21/121 reads (17%) | called by mutect2, pindel, varscan2
- MORC4 | c.2003G>T p.R668I | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- N4BP2L2 | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 97/295 reads (33%) | called by muse, mutect2, varscan2
- NPC1L1 | c.77C>T p.T26I | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCF11 | c.2236G>C p.A746P | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.36); called by muse, mutect2
- POLR1G | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- PPP2R2C | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRMT1 | c.596A>G p.Y199C | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RC3H2 | c.2954G>A p.G985E | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SDAD1 | c.2051A>T p.K684I | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SDAD1 | c.2050A>C p.K684Q | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPON1 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, varscan2
- TCF25 | c.2029T>C p.*677Rext*26 | Nonstop Mutation (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
- TENT5C | c.932G>C p.R311P | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); called by muse, mutect2
- THAP7 | c.916A>T p.S306C | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- VWA7 | c.1163dup p.G389Wfs*5 | Frame Shift Ins (INS) | VAF 28/118 reads (24%) | called by pindel, varscan2
- ZNF285 | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 63/153 reads (41%) | called by muse, mutect2, varscan2
- ZNF385D | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF714 | c.791A>C p.K264T | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTL7A | c.1158C>A p.T386= | Silent (SNP) | VAF 39/188 reads (21%) | catalogued as rs771565075; called by muse, mutect2, varscan2
- ACTRT1 | c.330G>A p.E110= | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as rs778867437; called by muse, mutect2, varscan2
- ADAMTS10 | c.1833G>A p.V611= | Silent (SNP) | VAF 77/177 reads (44%) | catalogued as rs1441445631; called by muse, mutect2, varscan2
- CACNA1I | c.5385G>A p.S1795= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as rs1259087407; called by muse, mutect2, varscan2
- CHD1L | c.2052C>G p.S684= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV63615306; called by muse, mutect2
- CRYBG3 | c.6045C>T p.S2015= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs774132231; called by muse, mutect2, varscan2
- HSPBAP1 | c.1014A>T p.T338= | Silent (SNP) | VAF 54/113 reads (48%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.237C>T p.F79= | Silent (SNP) | VAF 38/94 reads (40%) | called by muse, varscan2
- IGLV3-1 | c.315C>T p.Y105= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as rs373828762; called by muse, varscan2
- IGSF1 | c.165G>A p.T55= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs368413413, COSV63837122; called by muse, mutect2, varscan2
- MICAL2 | c.2106G>A p.E702= | Silent (SNP) | VAF 27/61 reads (44%) | called by muse, mutect2, varscan2
- MYO7A | c.3282C>A p.G1094= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV68687581; called by muse, mutect2, varscan2
- OR4C15 | c.924A>T p.I308= (on ENST00000314644; = p.I254= on NM_001001920.2) | Silent (SNP) | VAF 164/300 reads (55%) | called by muse, varscan2
- PCDHB13 | c.849C>T p.F283= | Silent (SNP) | VAF 52/242 reads (21%) | called by muse, varscan2
- POLD1 | c.3057C>T p.L1019= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs1221582721; called by muse, mutect2, varscan2
- SBNO2 | c.2121C>G p.V707= | Silent (SNP) | VAF 18/97 reads (19%) | called by muse, mutect2, varscan2
- TMCC2 | c.1707C>T p.L569= | Silent (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- TUBB4A | c.1116G>A p.T372= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs759818650, COSV51154927; called by muse, mutect2, varscan2
- AC011410.1 | n.188_194del | RNA (DEL) | VAF 56/245 reads (23%) | called by mutect2, pindel, varscan2
- ADAMTS5 | c.*1991dup | 3'UTR (INS) | VAF 28/85 reads (33%) | catalogued as rs1007794458; called by mutect2, varscan2
- AL353747.1 | n.38C>T | RNA (SNP) | VAF 24/54 reads (44%) | called by muse, varscan2
- APOBEC3F | c.*1284G>A | 3'UTR (SNP) | VAF 87/249 reads (35%) | called by muse, mutect2, varscan2
- APRT | c.*158C>A | 3'UTR (SNP) | VAF 43/141 reads (30%) | called by muse, mutect2, varscan2
- BDKRB1 | chr14:96268772 A>C | 3'Flank (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- BEND7 | c.1081+1229C>T | Intron (SNP) | VAF 19/65 reads (29%) | catalogued as rs556744756; called by muse, mutect2, varscan2
- BTBD1 | c.*381T>G | 3'UTR (SNP) | VAF 96/251 reads (38%) | called by muse, mutect2, varscan2
- C8orf37 | c.*400T>G | 3'UTR (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81946848 T>A | 3'Flank (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- CBLN4 | c.-965C>T | 5'UTR (SNP) | VAF 91/222 reads (41%) | catalogued as rs987261498; called by muse, mutect2, varscan2
- CBX4 | c.*283G>A | 3'UTR (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- CCDC180 | c.*10C>T | 3'UTR (SNP) | VAF 146/624 reads (23%) | called by muse, mutect2, varscan2
- CDH8 | c.-18T>A | 5'UTR (SNP) | VAF 23/76 reads (30%) | called by muse, mutect2, varscan2
- CDK6 | c.*161T>G | 3'UTR (SNP) | VAF 18/42 reads (43%) | called by muse, mutect2, varscan2
- CDT1 | c.*4T>A | 3'UTR (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- CERS3 | c.*445A>G | 3'UTR (SNP) | VAF 73/171 reads (43%) | called by muse, mutect2, varscan2
- CHD6 | c.-20T>C | 5'UTR (SNP) | VAF 51/140 reads (36%) | called by muse, mutect2, varscan2
- CLCN5 | chrX:50093567 del A | 3'Flank (DEL) | VAF 14/34 reads (41%) | catalogued as rs782016308; called by mutect2, varscan2
- CTBP2 | c.58+11795C>T | Intron (SNP) | VAF 34/88 reads (39%) | catalogued as rs200085060; called by muse, mutect2, varscan2
- CTNNA2 | c.*707A>G | 3'UTR (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- CYP8B1 | c.*967_*968del | 3'UTR (DEL) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- DLG3 | c.2256-131G>A | Intron (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- DLL3 | c.1093+25G>A | Intron (SNP) | VAF 65/163 reads (40%) | catalogued as rs774977551; called by muse, mutect2, varscan2
- DLX2 | c.*749T>G | 3'UTR (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- DNAJC21 | c.*3622T>A | 3'UTR (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2, varscan2
- DPP10 | c.*3279C>T | 3'UTR (SNP) | VAF 18/66 reads (27%) | catalogued as rs75254826; called by muse, mutect2, varscan2
- DSCR8 | n.336G>A | RNA (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- EPB41L4A | chr5:112419773 G>A | 5'Flank (SNP) | VAF 43/184 reads (23%) | called by muse, mutect2, varscan2
- FAM110B | c.*235G>A | 3'UTR (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- FAM122C | c.345+1990T>G | Intron (SNP) | VAF 47/136 reads (35%) | called by muse, mutect2, varscan2
- FAM43B | c.*118C>T | 3'UTR (SNP) | VAF 39/97 reads (40%) | called by muse, mutect2, varscan2
- HHIPL1 | c.*3170T>A | 3'UTR (SNP) | VAF 7/174 reads (4%) | called by muse, mutect2
- HIPK3 | c.*2276_*2277dup | 3'UTR (INS) | VAF 10/26 reads (38%) | catalogued as rs1003499725; called by mutect2, varscan2
- IL13RA1 | c.1010-3440C>T | Intron (SNP) | VAF 79/262 reads (30%) | catalogued as rs1203306184; called by muse, mutect2, varscan2
- IRAK1 | c.-74A>G | 5'UTR (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- IYD | c.*4088G>C | 3'UTR (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- KDR | c.*610C>T | 3'UTR (SNP) | VAF 52/160 reads (33%) | catalogued as rs367562624; called by muse, mutect2, varscan2
- KLHL33 | c.-45+16C>T | Intron (SNP) | VAF 15/212 reads (7%) | called by muse, mutect2
- KLHL4 | c.*388A>T | 3'UTR (SNP) | VAF 16/44 reads (36%) | catalogued as rs903104706, COSV64141916; called by muse, varscan2
- LPAR1 | chr9:111038454 G>A | 5'Flank (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- LRRC69 | c.933+6013C>A | Intron (SNP) | VAF 57/190 reads (30%) | called by muse, mutect2, varscan2
- LRRC8B | c.*4477A>T | 3'UTR (SNP) | VAF 21/66 reads (32%) | catalogued as rs1557632965; called by muse, mutect2, varscan2
- LUZP2 | c.*3312A>C | 3'UTR (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2
- MAGEB5 | c.*84A>C | 3'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- MAPK15 | c.287-46C>T | Intron (SNP) | VAF 29/45 reads (64%) | catalogued as rs1402801422, COSV62028551; called by muse, mutect2, varscan2
- MCM3AP | chr21:46230387 C>A | 3'Flank (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- MCOLN3 | c.1096-28C>A | Intron (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- MID1 | c.*886T>C | 3'UTR (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851405 T>C | 5'Flank (SNP) | VAF 47/146 reads (32%) | called by muse, mutect2, varscan2
- MMP16 | c.*4357G>A | 3'UTR (SNP) | VAF 22/53 reads (42%) | catalogued as rs775002150; called by muse, mutect2, varscan2
- MTMR2 | c.*2207C>T | 3'UTR (SNP) | VAF 16/67 reads (24%) | catalogued as rs1033436034; called by muse, mutect2, varscan2
- MTREX | c.*700A>T | 3'UTR (SNP) | VAF 17/80 reads (21%) | catalogued as COSV53307103; called by muse, mutect2, varscan2
- NDUFS7 | c.545-946C>T | Intron (SNP) | VAF 84/163 reads (52%) | catalogued as rs1469867858; called by muse, mutect2, varscan2
- NOS3 | c.1752+962C>G | Intron (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- NXPE4 | c.*272A>G | 3'UTR (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- OR51C1P | c.*99T>A | 3'UTR (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- PCDH17 | c.*324A>T | 3'UTR (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- PJA2 | c.*649G>T | 3'UTR (SNP) | VAF 42/96 reads (44%) | called by muse, mutect2, varscan2
- PLEKHA1 | c.*639A>G | 3'UTR (SNP) | VAF 34/101 reads (34%) | catalogued as rs1565363183; called by muse, mutect2, varscan2
- PQBP1 | chrX:48898194 G>C | 5'Flank (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- PUS10 | c.615+57T>C | Intron (SNP) | VAF 14/32 reads (44%) | called by muse, varscan2
- PXYLP1 | c.*665C>T | 3'UTR (SNP) | VAF 15/85 reads (18%) | called by muse, mutect2, varscan2
- REG1B | c.64+44C>A | Intron (SNP) | VAF 52/155 reads (34%) | called by muse, mutect2, varscan2
- REP15 | c.-78_-74dup | 5'UTR (INS) | VAF 15/45 reads (33%) | called by mutect2, pindel, varscan2
- RIC8A | c.*141C>A | 3'UTR (SNP) | VAF 24/582 reads (4%) | catalogued as rs1260867973; called by muse, mutect2
- RNF44 | c.*1738A>G | 3'UTR (SNP) | VAF 65/128 reads (51%) | called by muse, mutect2, varscan2
- SCN3A | c.*2504G>T | 3'UTR (SNP) | VAF 27/75 reads (36%) | called by muse, mutect2, varscan2
- SEC22C | c.*3791G>A | 3'UTR (SNP) | VAF 35/150 reads (23%) | called by muse, mutect2, varscan2
- SEMA3E | c.-368_-367insG | 5'UTR (INS) | VAF 8/20 reads (40%) | called by mutect2, varscan2
- SHISA9 | c.-66G>A | 5'UTR (SNP) | VAF 6/13 reads (46%) | catalogued as rs1469084938; called by muse, mutect2
- SLITRK1 | c.-221C>T | 5'UTR (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- ST6GALNAC2 | chr17:76561681 G>A | 3'Flank (SNP) | VAF 49/156 reads (31%) | catalogued as rs1274575221; called by muse, mutect2, varscan2
- STOML3 | c.*395C>T | 3'UTR (SNP) | VAF 28/79 reads (35%) | called by muse, mutect2, varscan2
- STX6 | c.-188A>C | 5'UTR (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- SUPT7L | c.14+85_14+89del | Intron (DEL) | VAF 42/110 reads (38%) | called by mutect2, pindel, varscan2
- SYNGAP1 | c.*515T>A | 3'UTR (SNP) | VAF 58/144 reads (40%) | called by muse, mutect2, varscan2
- TCP1 | c.1098-46A>T | Intron (SNP) | VAF 15/33 reads (45%) | catalogued as rs561923778, COSV58458825; called by muse, mutect2, varscan2
- TIMM8A | c.-25T>G | 5'UTR (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- TMSB4X | c.-45G>C | 5'UTR (SNP) | VAF 46/124 reads (37%) | called by muse, mutect2, varscan2
- TOX3 | c.87+27135C>T | Intron (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- UBE2D3 | chr4:102796715 G>C | 3'Flank (SNP) | VAF 107/270 reads (40%) | called by muse, mutect2, varscan2
- VAV2 | c.*1712G>A | 3'UTR (SNP) | VAF 82/176 reads (47%) | catalogued as rs1037627725; called by muse, mutect2, varscan2
- WASF4P | n.1193C>T | RNA (SNP) | VAF 13/65 reads (20%) | catalogued as rs1556876008; called by muse, mutect2, varscan2
- ZFYVE16 | c.-32A>C | 5'UTR (SNP) | VAF 44/186 reads (24%) | called by muse, mutect2, varscan2
- ZNF280C | c.*2138del | 3'UTR (DEL) | VAF 26/66 reads (39%) | catalogued as rs1247994001; called by mutect2, varscan2
- ZNF354C | c.*2485G>A | 3'UTR (SNP) | VAF 21/47 reads (45%) | catalogued as rs888841587; called by muse, mutect2, varscan2
- ZZZ3 | c.*149C>T | 3'UTR (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
